CCDI case PBBRPL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cf49605c-d344-4b59-923a-9546d469e250

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 14.9 years (5,438 days).

Biospecimens (3 samples)
- Sample 0DGJ4O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGJ62: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGJ85: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
